Somatic mutation profile of tumor specimen SM-JU32X (aliquot 7316UP-3741) from CPTAC case C1230738, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Occipital lobe; Tumor grade: G4.
Specimen SM-JU32X: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67565657-9094-4d08-ae3f-62df26d2479b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105281 (Blood Derived Normal), aliquot 7316UP-2837-1105281; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6f2f4cf-f11c-4715-a339-d8e7bd22ae76

The open-access MAF lists 108 somatic variants for this specimen: 75 protein-altering or splice-affecting, 23 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 23, Intron 6, Frame Shift Del 6, Nonsense Mutation 3, Splice Site 3, 3'UTR 2, In Frame Ins 1, 5'Flank 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MFSD8 | c.863+1G>A p.X288_splice | Splice Site (SNP) | VAF 39/185 reads (21%) | catalogued as rs200319160, CS091348; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>C p.M237I | Missense Mutation (SNP) | VAF 322/454 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; called by muse, mutect2, varscan2
- ABCA10 | c.215T>C p.M72T | Missense Mutation (SNP) | VAF 100/156 reads (64%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs1362810033; called by muse, mutect2, varscan2
- ACO2 | c.1613A>T p.D538V | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs1012815978; called by muse, mutect2, varscan2
- ANKRD50 | c.3991A>T p.M1331L | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs200657431; called by muse, mutect2, varscan2
- BANK1 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs893222221, COSV100536056; called by muse, mutect2, varscan2
- BEND2 | c.2293G>A p.V765I | Missense Mutation (SNP) | VAF 139/371 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs930593539, COSV66220222; called by muse, mutect2, varscan2
- CCDC185 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs138307328; called by muse, mutect2, varscan2
- CHFR | c.1805A>G p.Y602C (on ENST00000432561 / NM_001161345.1; = p.Y561C on NM_018223.2) | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1356919481, COSV57177310; called by muse, mutect2
- CROCC | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1249043016; called by muse, mutect2, varscan2
- CSH2 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 306/433 reads (71%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs775328717, COSV61080906; called by muse, mutect2, varscan2
- CTDSPL2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV52945054; called by muse, mutect2, varscan2
- ELL3 | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 81/378 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55854970; called by muse, mutect2, varscan2
- FBXW11 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 103/201 reads (51%) | catalogued as rs995419585, COSV51605516; called by muse, mutect2, varscan2
- GRIP1 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 132/399 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs377476830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GSN | c.1619del p.G540Vfs*5 | Frame Shift Del (DEL) | VAF 122/613 reads (20%) | catalogued as COSV57999977; called by mutect2, pindel, varscan2
- GYS2 | c.405G>A p.W135* | Nonsense Mutation (SNP) | VAF 23/274 reads (8%) | catalogued as COSV53924138; called by muse, mutect2
- HMCN1 | c.16783C>T p.R5595* | Nonsense Mutation (SNP) | VAF 38/212 reads (18%) | catalogued as rs1412752744, COSV54884056, COSV99633533; called by muse, mutect2, varscan2
- IGLC7 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 456/685 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs373815473; called by muse, mutect2, varscan2
- KRT18 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 133/398 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as rs1217770008; called by muse, mutect2, varscan2
- LCE3A | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 191/529 reads (36%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs1469550473, COSV59551162; called by muse, mutect2, varscan2
- NEURL1 | c.505G>C p.A169P | Missense Mutation (SNP) | VAF 236/355 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV63914659; called by muse, mutect2, varscan2
- PTPRQ | c.1934C>T p.T645M (on ENST00000616559; = p.T603M on NM_001145026.2) | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs924539666; called by muse, mutect2, varscan2
- RGS22 | c.40A>G p.T14A | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs751002688; called by muse, mutect2, varscan2
- RIMS2 | c.1223G>A p.R408Q (on ENST00000666250 / NM_001348490.2; = p.R216Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs376489252, COSV51663807; called by muse, mutect2, varscan2
- SERPINB11 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs369601900; called by muse, mutect2, varscan2
- SERPINB12 | c.645G>A p.A215= | Splice Region (SNP) | VAF 28/77 reads (36%) | catalogued as rs1014451613, COSV54034944; called by muse, mutect2, varscan2
- SERPINH1 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 89/383 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.427); catalogued as rs753734711; called by muse, mutect2, varscan2
- TFAP2D | c.374C>A p.S125Y | Missense Mutation (SNP) | VAF 66/371 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99148636; called by muse, mutect2, varscan2
- ZNF705G | c.235+1G>A p.X79_splice | Splice Site (SNP) | VAF 26/588 reads (4%) | catalogued as rs1241055369; called by muse, mutect2
- ZNF99 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV68054631; called by muse, mutect2, varscan2
- ACTG2 | c.395_399del p.A132Vfs*25 | Frame Shift Del (DEL) | VAF 32/328 reads (10%) | called by mutect2, pindel
- ADAMTS16 | c.183C>G p.D61E | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARMC5 | c.391_392del p.L131Gfs*55 | Frame Shift Del (DEL) | VAF 75/724 reads (10%) | called by mutect2, pindel, varscan2
- CD37 | c.37T>C p.Y13H | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNTN3 | c.3053T>A p.I1018K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CSMD3 | c.2053G>A p.V685I (on ENST00000297405 / NM_001363185.1; = p.V581I on NM_052900.3) | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CSNK1G1 | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CTBP1 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.176); called by muse, mutect2
- CUL2 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 65/118 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DHRS12 | c.598G>T p.V200F (on ENST00000444610 / NM_001377930.1; = p.V151F on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- DHRS12 | c.597G>A p.M199I (on ENST00000444610 / NM_001377930.1; = p.M150I on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOP1A | c.2237C>A p.A746D | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DPEP1 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ECPAS | c.4685T>C p.M1562T | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EDEM1 | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EFHB | c.876A>T p.K292N | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2
- FHOD3 | c.1640G>C p.G547A (on ENST00000359247 / NM_001281739.3; = p.G564A on NM_025135.5) | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.009); called by muse, mutect2
- FRYL | c.8707_8722del p.T2903* | Frame Shift Del (DEL) | VAF 22/150 reads (15%) | called by mutect2, pindel
- GNAQ | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- IRS4 | c.775A>T p.T259S | Missense Mutation (SNP) | VAF 26/581 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.264); called by muse, mutect2
- ITPKB | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, mutect2
- KIAA1958 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF24 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- KIFC3 | c.1519C>A p.Q507K | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- MRGPRX1 | c.86G>T p.S29I | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOP56 | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 130/375 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NPM3 | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 37/304 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- OR51S1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- OR5D16 | c.721T>C p.S241P | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OR5K4 | c.887A>C p.N296T | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PDHA2 | c.1021A>G p.R341G | Missense Mutation (SNP) | VAF 28/516 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2
- POLRMT | c.3211del p.V1071Sfs*21 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel
- RELN | c.5734C>A p.P1912T | Missense Mutation (SNP) | VAF 76/313 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- RUNX1 | c.1270G>A p.D424N (on ENST00000344691 / NM_001001890.3; = p.D451N on NM_001754.5) | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- SAMD9L | c.3427A>T p.S1143C | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- SIN3A | c.1781A>T p.D594V | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC28A3 | c.1023+2T>A p.X341_splice | Splice Site (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- STAB1 | c.7334T>C p.I2445T | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- STRAP | c.82_83insTTT p.P27_Y28insF | In Frame Ins (INS) | VAF 38/342 reads (11%) | called by mutect2, pindel
- TRHDE | c.744C>G p.F248L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- WDR97 | c.1120G>A p.G374S | Missense Mutation (SNP) | VAF 77/369 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- XKR6 | c.635T>C p.V212A | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2
- ZBTB7A | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF670 | c.458del p.L153Pfs*9 | Frame Shift Del (DEL) | VAF 26/195 reads (13%) | called by mutect2, pindel, varscan2
- ADGRD1 | c.1551C>T p.S517= | Silent (SNP) | VAF 97/269 reads (36%) | catalogued as rs1325779017, COSV55450141; called by muse, mutect2, varscan2
- ADH1C | c.870T>C p.S290= | Silent (SNP) | VAF 15/242 reads (6%) | catalogued as rs1476631183; called by muse, mutect2
- AR | c.1557T>C p.C519= | Silent (SNP) | VAF 25/554 reads (5%) | called by muse, mutect2
- C6orf15 | c.289A>C p.R97= | Silent (SNP) | VAF 16/221 reads (7%) | called by muse, mutect2
- CBX4 | c.405G>A p.K135= | Silent (SNP) | VAF 137/425 reads (32%) | called by muse, mutect2, varscan2
- COL10A1 | c.60T>C p.F20= | Silent (SNP) | VAF 83/258 reads (32%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.804A>G p.Q268= | Silent (SNP) | VAF 86/221 reads (39%) | catalogued as rs377098745, COSV50407482; called by muse, mutect2, varscan2
- CXorf65 | c.42G>T p.L14= | Silent (SNP) | VAF 56/208 reads (27%) | called by muse, mutect2, varscan2
- CYFIP1 | c.249G>A p.L83= | Silent (SNP) | VAF 68/193 reads (35%) | called by muse, mutect2, varscan2
- EOMES | c.636C>T p.A212= | Silent (SNP) | VAF 17/352 reads (5%) | called by muse, mutect2
- FAM149A | c.1365A>T p.A455= (on ENST00000356371 / NM_001367768.2; = p.A164= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 66/273 reads (24%) | called by muse, mutect2, varscan2
- GTPBP3 | c.411G>A p.P137= | Silent (SNP) | VAF 36/123 reads (29%) | called by muse, mutect2, varscan2
- HNRNPA1L2 | c.876A>G p.G292= | Silent (SNP) | VAF 12/338 reads (4%) | called by muse, mutect2
- JADE1 | c.1020C>T p.T340= | Silent (SNP) | VAF 42/104 reads (40%) | called by mutect2, varscan2
- JMJD6 | c.1020C>T p.S340= | Silent (SNP) | VAF 16/210 reads (8%) | catalogued as rs746733650; called by muse, mutect2
- MARCHF7 | c.108C>T p.T36= | Silent (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- MYO3A | c.4411C>A p.R1471= | Silent (SNP) | VAF 61/338 reads (18%) | called by muse, mutect2, varscan2
- PAN2 | c.312C>T p.A104= | Silent (SNP) | VAF 54/149 reads (36%) | called by muse, mutect2, varscan2
- SLC30A1 | c.1113A>G p.E371= | Silent (SNP) | VAF 22/328 reads (7%) | called by muse, mutect2
- TEX11 | c.1470C>T p.N490= (on ENST00000344304; = p.N475= on NM_031276.3) | Silent (SNP) | VAF 51/141 reads (36%) | catalogued as rs1168415970, COSV60234072; called by muse, mutect2, varscan2
- TFRC | c.1893C>T p.D631= | Silent (SNP) | VAF 59/229 reads (26%) | called by muse, mutect2, varscan2
- ZAP70 | c.1752C>T p.P584= | Silent (SNP) | VAF 63/189 reads (33%) | catalogued as rs199627332; called by muse, mutect2, varscan2
- ZNF99 | c.813C>A p.T271= | Silent (SNP) | VAF 88/203 reads (43%) | catalogued as COSV68055425; called by muse, mutect2, varscan2
- AK2 | c.*2332_*2333del | 3'UTR (DEL) | VAF 74/404 reads (18%) | called by pindel, varscan2
- CCDC88A | c.5551+397G>A | Intron (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- HS1BP3 | c.920+1601C>G | Intron (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- IGFALS | c.*149del | 3'UTR (DEL) | VAF 4/32 reads (13%) | catalogued as rs982418342; called by pindel, varscan2
- MAPKBP1 | c.328-340G>A | Intron (SNP) | VAF 210/474 reads (44%) | catalogued as rs1000202086; called by muse, mutect2, varscan2
- MRRFP1 | n.341A>G | RNA (SNP) | VAF 51/163 reads (31%) | called by muse, mutect2, varscan2
- PKD1L2 | chr16:81139574 G>T | 5'Flank (SNP) | VAF 106/349 reads (30%) | called by muse, mutect2, varscan2
- SPEN | c.404+1137A>G | Intron (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- TINAG | c.624+23G>A | Intron (SNP) | VAF 92/228 reads (40%) | catalogued as rs752360078; called by muse, mutect2, varscan2
- ZCWPW2 | c.658-3047A>T | Intron (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2
